Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3715, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3715-01A (Primary Tumor).

Diagnosis:

Right hemicolectomy preparation with a poorly differentiated adenosquamous carcinoma in the ascending colon of histopathological differentiation grade G3, with ulceration of the inner surface of the tumor, peritumorous chronic recurrent concomitant inflammation, with carcinomatous lymphangitis, tumor infiltration in the parietal layers of the colon as far as the pericolic fatty connective tissue, with moderately chronic lymphadenitis of the tumor-free lymph nodes (0/12), chronic appendicitis and with tumor-free overview slices from the resection margins, from the region of the vessel ligature and from the adjoining omental fatty tissue.

According to the sections examined, the tumor spreading from the colon carcinoma corresponds a tumor stage of pT3, pN0, MX, L1, R0.

Source: NCI Genomic Data Commons file 7d0a031c-d7fe-4b10-b784-385abb549a62 (TCGA-AA-3715.CC2F2E2C-FCC2-4D75-9589-A9EC31FBE3AC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).